Somatic mutation profile of tumor specimen TARGET-10-PATJLT-09A (aliquot TARGET-10-PATJLT-09A-01D) from TARGET case TARGET-10-PATJLT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.1 years (4,416 days).
Specimen TARGET-10-PATJLT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 838dfe7d-4c91-4e66-87e0-3d099c867caa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATJLT-10A (Blood Derived Normal), aliquot TARGET-10-PATJLT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af7502a4-1813-42d3-a995-73a5c61e5c0d

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 12/192 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2
- CCDC88C | c.6070G>T p.E2024* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV57795799; called by muse, mutect2, varscan2
- CCKBR | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV58098388; called by muse, mutect2, varscan2
- DIDO1 | c.5879G>C p.R1960T | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV56613001; called by muse, mutect2, varscan2
- IGHE | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1555457055; called by muse, mutect2, varscan2
- PTEN | c.737dup p.L247Vfs*6 | Frame Shift Ins (INS) | VAF 40/108 reads (37%) | called by pindel, varscan2
- FARSB | c.1701C>T p.D567= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs141929079; called by muse, mutect2, varscan2
- NAMPTP1 | n.341C>T | RNA (SNP) | VAF 106/214 reads (50%) | catalogued as rs753947867; called by muse, mutect2, varscan2
- PDLIM7 | c.399-128C>T | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
